FM case AD11228 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/5c9d56b6-dca0-41c5-ac50-8390b69bda35

Male, 23.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
